Somatic mutation profile of tumor specimen 0DHY54 from CCDI case PBBVCN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.5 years (6,774 days).
Specimen 0DHY54: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41f03446-d302-4141-beec-3ad0839fb979.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9029f05f-952c-48dd-9d04-c45486cfc6f1

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPPA4 | c.660del p.E220Dfs*46 | Frame Shift Del (DEL) | VAF 99/539 reads (18%) | called by mutect2, pindel, varscan2
- FCGBP | c.4159T>G p.C1387G | Missense Mutation (SNP) | VAF 16/499 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2
- COL27A1 | c.4939-39G>C | Intron (SNP) | VAF 18/257 reads (7%) | called by muse, mutect2
